Somatic mutation profile of tumor specimen TCGA-CD-5799-01A (aliquot TCGA-CD-5799-01A-11D-1600-08) from TCGA case TCGA-CD-5799, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 45.3 years (16,533 days).
Specimen TCGA-CD-5799-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fb8ee95-ae1c-4752-9026-d7518578cc2d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CD-5799-10A (Blood Derived Normal), aliquot TCGA-CD-5799-10A-01D-1600-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e8029aa-561f-47bd-bec7-dfb190d47b85

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 11/16 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- SMAD4 | c.1082_1096del p.R361_G365del | In Frame Del (DEL) | VAF 54/102 reads (53%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 43/76 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGBL1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.249); catalogued as COSV69803984; called by muse, mutect2, varscan2
- AURKC | c.707A>T p.Y236F (on ENST00000302804 / NM_001015878.2; = p.Y202F on NM_003160.3) | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV57139388; called by muse, mutect2, varscan2
- C3 | c.1513C>T p.R505C | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748352684, COSV55577398; called by muse, mutect2, varscan2
- CCDC141 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs146458136; called by muse, mutect2, varscan2
- CCDC34 | c.1028C>A p.P343H | Missense Mutation (SNP) | VAF 104/182 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV60821310; called by muse, mutect2, varscan2
- CDH1 | c.1199A>T p.D400V | Missense Mutation (SNP) | VAF 159/242 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55730476, COSV55737245; called by muse, mutect2, varscan2
- COL5A3 | c.2050C>A p.H684N | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53415565; called by muse, mutect2, varscan2
- CTLA4 | c.272T>C p.M91T | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs1065442, COSV55592801; called by muse, mutect2, varscan2
- DNAH17 | c.3752C>T p.A1251V | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.245); catalogued as rs374735478; called by muse, mutect2, varscan2
- EPB41L3 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 52/123 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV59461655; called by muse, mutect2, varscan2
- GABRB3 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 76/229 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1197311612, COSV54661471, COSV54667048; called by muse, mutect2, varscan2
- GHSR | c.400A>T p.I134F | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53840576; called by muse, mutect2, varscan2
- ITIH3 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.18); catalogued as rs548417682, COSV69649645; called by mutect2, varscan2
- MXD3 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs372775369; called by muse, mutect2, varscan2
- NOL8 | c.2447G>C p.S816T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as COSV62636512; called by muse, mutect2, varscan2
- OPN5 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.026); catalogued as COSV55246614; called by muse, mutect2, varscan2
- OR1J4 | c.295A>C p.T99P | Missense Mutation (SNP) | VAF 168/307 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as COSV61590098; called by muse, mutect2, varscan2
- OR6N1 | c.858C>A p.N286K | Missense Mutation (SNP) | VAF 63/303 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58648940, COSV58649658; called by muse, mutect2
- PRPF6 | c.2191G>A p.A731T | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.1); catalogued as COSV53874897; called by muse, mutect2
- PSMD2 | c.1863C>G p.D621E | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0.003); catalogued as COSV59530762, COSV59530806; called by muse, mutect2, varscan2
- SCAF4 | c.2998T>G p.F1000V | Missense Mutation (SNP) | VAF 17/424 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as COSV54256745; called by muse, mutect2
- ZNF257 | c.1133G>C p.G378A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); catalogued as COSV101448163, COSV71306449, COSV71310253; called by muse, mutect2, varscan2
- CERS6 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- CAND2 | c.2199T>C p.S733= (on ENST00000456430 / NM_001162499.2; = p.S640= on NM_012298.3) | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as COSV55992279; called by muse, mutect2, varscan2
- KNDC1 | c.1224C>T p.A408= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV58841751, COSV58842355; called by muse, mutect2, varscan2
- LINGO2 | c.972C>T p.R324= | Silent (SNP) | VAF 59/99 reads (60%) | catalogued as rs138682295, COSV100430124; called by muse, mutect2, varscan2
- MAST4 | c.2106C>T p.T702= (on ENST00000403625 / NM_001164664.2; = p.T513= on NM_015183.3) | Silent (SNP) | VAF 98/259 reads (38%) | catalogued as COSV55134171; called by muse, mutect2, varscan2
- MBOAT1 | c.1128G>A p.L376= | Silent (SNP) | VAF 33/115 reads (29%) | catalogued as rs767429912, COSV61126709; called by muse, mutect2, varscan2
- PCDHA11 | c.1293G>A p.S431= | Silent (SNP) | VAF 26/190 reads (14%) | catalogued as COSV56527826; called by muse, mutect2, varscan2
- PCDHA11 | c.2169G>A p.S723= | Silent (SNP) | VAF 3/50 reads (6%) | catalogued as COSV56527842; called by muse, mutect2
- SERPINA7 | c.798G>A p.L266= | Silent (SNP) | VAF 12/226 reads (5%) | catalogued as COSV59666663; called by muse, mutect2
- TIAM1 | c.4425C>T p.P1475= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs768613628, COSV54552241; called by muse, mutect2, varscan2
